Somatic mutation profile of tumor specimen TCGA-76-6663-01A (aliquot TCGA-76-6663-01A-11D-1845-08) from TCGA case TCGA-76-6663, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 44.2 years (16,126 days).
Specimen TCGA-76-6663-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c40e0af-33d3-4dfc-ab0a-1cad8e9d17ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6663-10A (Blood Derived Normal), aliquot TCGA-76-6663-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56cd0c03-cc81-402f-b725-034f0906e116

The open-access MAF lists 58 somatic variants for this specimen: 38 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 18, Frame Shift Del 2, Nonsense Mutation 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as rs397514641, CM000774, COSV62197492; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG1 | c.1966G>A p.G656R | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.657); catalogued as rs760071193, COSV59206738; called by muse, mutect2, varscan2
- CERS3 | c.933G>T p.L311F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52570654; called by muse, mutect2, varscan2
- CLDN19 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs531931336, COSV56418430; called by muse, mutect2, varscan2
- COPS3 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV52006278; called by muse, mutect2, varscan2
- EPHA6 | c.1152C>A p.N384K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV67579358; called by muse, mutect2, varscan2
- FRMPD4 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs779596855, COSV66218014; called by muse, mutect2, varscan2
- GCNA | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as COSV65467422; called by muse, mutect2, varscan2
- GLI1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57363925; called by muse, mutect2, varscan2
- GPRC6A | c.2495C>A p.P832H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59953982; called by muse, mutect2, varscan2
- HYDIN | c.10129C>A p.R3377S | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV101151299, COSV101157939; called by muse, mutect2, varscan2
- MATK | c.830C>T p.T277M (on ENST00000310132 / NM_139355.3; = p.T278M on NM_002378.4) | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489778655, COSV59555471; called by muse, mutect2, varscan2
- MSX2 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.381); catalogued as COSV53327614; called by muse, mutect2, varscan2
- MXRA5 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs768847893, COSV54231645; called by muse, mutect2
- MYO1B | c.2903T>C p.L968P (on ENST00000304164; = p.L910P on NM_012223.5) | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58433563; called by muse, mutect2, varscan2
- ONECUT2 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1349085016, COSV72153056; called by muse, mutect2, varscan2
- OR2M2 | c.961T>A p.L321M | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.045); catalogued as COSV62898742; called by muse, mutect2, varscan2
- PANX2 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1269821607, COSV50296228; called by muse, mutect2, varscan2
- PCDHA11 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV56490219; called by muse, mutect2, varscan2
- PCDHB4 | c.1846G>A p.V616M | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as COSV52024048; called by muse, mutect2, varscan2
- PDGFRB | c.1859A>T p.H620L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.718); catalogued as COSV55806996; called by muse, mutect2
- PDZD4 | c.1421G>C p.G474A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as COSV51248038; called by muse, varscan2
- PTPN14 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65285381; called by muse, mutect2, varscan2
- PXDN | c.2575T>G p.S859A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV53239081; called by mutect2, varscan2
- RB1 | c.2384C>A p.S795* | Nonsense Mutation (SNP) | VAF 45/123 reads (37%) | catalogued as COSV57313650, COSV57316655; called by muse, mutect2, varscan2
- RPS6KA1 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs758148586, COSV64809878; called by muse, mutect2, varscan2
- SIPA1L2 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs780220404, COSV53390854, COSV99479294; called by muse, mutect2, varscan2
- SLC17A7 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV55548469; called by muse, mutect2, varscan2
- SPTA1 | c.509T>C p.I170T | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV63755899; called by muse, mutect2, varscan2
- TAOK2 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV54237749; called by muse, mutect2, varscan2
- TBC1D8B | c.655_656del p.S219Yfs*19 | Frame Shift Del (DEL) | VAF 34/110 reads (31%) | catalogued as rs759889636; called by pindel, varscan2
- TTN | c.38716G>A p.E12906K (on ENST00000591111; = p.E5482K on NM_003319.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | PolyPhen benign (0.077); catalogued as rs761539202, COSV59933910; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.3070G>A p.V1024I (on ENST00000591111; = p.V978I on NM_003319.4) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | PolyPhen benign (0.073); catalogued as rs368770038, COSV60207473; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TUBB4A | c.1286C>T p.T429M | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.703); catalogued as rs1568409002, COSV51158245; called by muse, mutect2, varscan2
- ZNF181 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); catalogued as rs748135943, COSV67626936; called by muse, mutect2, varscan2
- ZNF75D | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 81/312 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV66133013; called by muse, mutect2, varscan2
- ZP2 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1018803445, COSV54814923; called by muse, mutect2, varscan2
- SFPQ | c.1064del p.T355Nfs*3 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- AC127029.3 | c.405C>T p.R135= | Silent (SNP) | VAF 70/252 reads (28%) | catalogued as rs751135936, COSV60111174; called by muse, mutect2, varscan2
- ADGRV1 | c.6849C>T p.G2283= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs374348614; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNC2 | c.2202C>T p.G734= | Silent (SNP) | VAF 52/89 reads (58%) | catalogued as rs376030025; ClinVar: not provided; called by muse, mutect2, varscan2
- CLCA1 | c.1023G>A p.G341= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as COSV52328880; called by muse, mutect2, varscan2
- CMTR1 | c.1536G>A p.A512= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as rs146308234; called by muse, mutect2, varscan2
- HCN1 | c.2367G>A p.S789= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV57512654; called by muse, mutect2, varscan2
- HNF4A | c.216C>T p.Y72= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as rs993173795, CM1310937, COSV57382004, COSV57385150; called by muse, mutect2, varscan2
- INTS1 | c.1419G>A p.A473= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs754047029, COSV67177389; called by muse, mutect2, varscan2
- LAMA1 | c.3918G>A p.T1306= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs754627841, COSV67539548; called by muse, mutect2, varscan2
- LINGO2 | c.1707G>T p.G569= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV58061252; called by muse, mutect2, varscan2
- MRGPRX1 | c.630G>A p.P210= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as rs1397347907, COSV57108074, COSV57110180; called by muse, mutect2, varscan2
- OR13C8 | c.210C>T p.D70= | Silent (SNP) | VAF 26/287 reads (9%) | catalogued as rs1404946766, COSV58611595; called by muse, mutect2
- PHF2 | c.420G>A p.P140= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs745919994, COSV63681744; called by muse, mutect2, varscan2
- PIK3C2G | c.180A>G p.E60= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV56816627; called by muse, mutect2, varscan2
- TRHDE | c.597G>A p.A199= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as rs1244170837, COSV53837800; called by muse, mutect2
- TTN | c.38529G>A p.K12843= (on ENST00000591111; = p.K5419= on NM_003319.4) | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV60164498; called by muse, mutect2, varscan2
- UHRF1BP1L | c.4149C>T p.T1383= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs1308880724, COSV54439282; called by muse, mutect2, varscan2
- ZNF536 | c.3297C>T p.H1099= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs765944372, COSV62819936, COSV62827596; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503129 T>C | 5'Flank (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- LAMA4 | c.195+97C>A | Intron (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99683558; called by muse, mutect2
